Somatic mutation profile of tumor specimen TCGA-S7-A7WT-01A (aliquot TCGA-S7-A7WT-01A-12D-A35I-08) from TCGA case TCGA-S7-A7WT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 74.8 years (27,311 days).
Specimen TCGA-S7-A7WT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54930ac3-f80a-4e1a-bb4d-7e9035dccd8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WT-10A (Blood Derived Normal), aliquot TCGA-S7-A7WT-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0d70c48-a014-4eac-b9c9-c767d1a868cc

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Splice Site 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.2680G>A p.G894R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs777820311, COSV59385902; called by muse, mutect2, varscan2
- ASB9 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1473100858, COSV66851236; called by muse, mutect2, varscan2
- CALCRL | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs761424831, COSV66474118; called by muse, mutect2, varscan2
- PSD4 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV55530701; called by muse, mutect2, varscan2
- APC | c.4788G>C p.Q1596H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ASH1L | c.6656_6665del p.R2219Pfs*70 (on ENST00000368346 / NM_001366177.2; = p.R2214Pfs*70 on NM_018489.3) | Frame Shift Del (DEL) | VAF 27/227 reads (12%) | called by mutect2, pindel
- BTBD10 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- CCR4 | c.733_747del p.F245_V249del | In Frame Del (DEL) | VAF 20/40 reads (50%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.3722A>G p.Q1241R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSDE1 | c.1356+1G>A p.X452_splice (on ENST00000358528 / NM_001007553.3; = p.X421_splice on NM_007158.6) | Splice Site (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.3894T>A p.D1298E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- IGHV1-45 | c.62T>G p.M21R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ITLN2 | c.409T>A p.S137T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MDC1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2
- TM9SF4 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- UBN1 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ALDH2 | c.396C>A p.V132= | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- ALS2 | c.2266T>C p.L756= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1329571370, COSV51890735; called by muse, mutect2, varscan2
- DST | c.1965C>T p.L655= (on ENST00000361203 / NM_001374722.1; = p.L329= on NM_001723.6) | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- KSR1 | c.1881C>T p.D627= (on ENST00000644974 / NM_001367810.1; = p.D512= on NM_014238.2) | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SLC4A2 | c.2034G>A p.T678= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs531007948; called by muse, varscan2
